Gene-level copy-number profile of tumor specimen TCGA-55-8615-01A from TCGA case TCGA-55-8615, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.9 years (24,786 days).
Specimen TCGA-55-8615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.54ad0aa9-f043-4909-84f5-d4bdcce98ce8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8615-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70522b4d-c261-48e1-a91e-f5d841ac7ed7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 331; copy number 3: 3,522; copy number 4: 24,780; copy number 5: 9,882; copy number 6: 7,702; copy number 7: 5,357; copy number 8: 4,081; copy number 9: 3,166; copy number 10: 531; copy number 11: 239; copy number 13: 80; copy number 14: 19; copy number 16: 59; copy number 23: 41; copy number 24: 2; copy number 26: 10; copy number 37: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8615-01A-11D-2389-01): tumor purity 0.57, ploidy 5.23, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,120 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–199,752,890, 1,464 genes, copy number 9 (broad region; genes not listed).
- chr1:204,154,819–205,813,748, 54 genes, copy number 9: REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1.
- chr2:12,598,987–16,855,284, 46 genes, copy number 13: AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1.
- chr2:53,470,447–56,386,172, 58 genes, copy number 16: AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93.
- chr2:69,829,660–70,422,678, 22 genes, copy number 10: GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2, BRD7P6, AC022201.1.
- chr2:71,130,632–71,984,434, 8 genes, copy number 10–16: MPHOSPH10, AC007881.1, PAIP2B, ZNF638, AC007878.1, RNU6-105P, DYSF, RPS20P10.
- chr2:83,594,956–85,310,387, 23 genes, copy number 14–26 (within-gene range 5–26): RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, RPS2P17, AC022210.1, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11.
- chr2:86,193,026–90,235,370, 162 genes, copy number 11 (broad region; genes not listed).
- chr2:101,696,850–102,240,002, 7 genes, copy number 11 (within-gene range 4–11): MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2.
- chr5:1,931,064–2,119,926, 1 gene, copy number 9 (within-gene range 8–9): AC124852.1.
- chr5:2,184,710–50,603,511, 635 genes, copy number 9–11 (broad region; genes not listed).
- chr6:65,836,930–67,546,754, 8 genes, copy number 14: ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P.
- chr7:70,972–55,433,742, 942 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:56,163,145–57,485,895, 80 genes, copy number 9 (broad region; genes not listed).
- chr8:150,584–6,407,142, 81 genes, copy number 9 (broad region; genes not listed).
- chr8:6,473,845–6,474,288, 1 gene, copy number 9: AC016065.2.
- chr8:16,598,758–20,950,175, 74 genes, copy number 9 (broad region; genes not listed).
- chr8:20,953,127–21,030,368, 4 genes, copy number 9: AC015468.1, AC015468.2, LINC02153, AC103719.1.
- chr8:23,385,783–24,077,158, 16 genes, copy number 9: ENTPD4, AC104561.1, AC104561.2, AC104561.4, AC104561.3, SLC25A37, RNU4-71P, SINHCAFP3, NKX3-1, NKX2-6, AC012574.1, AC012574.2, AC012119.2, AC012119.1, STC1, RNU1-148P.
- chr8:28,089,673–28,343,355, 6 genes, copy number 9 (within-gene range 4–9): ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC.
- chr10:4,871,901–6,625,346, 58 genes, copy number 10: AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1, RPL32P23, RBM17, PFKFB3, RN7SKP78, MIR3155A, MIR3155B, AL157395.1, Y_RNA, LINC02649, SDCBPP1, LINC02656, PRKCQ, PRKCQ-AS1, LINC02648.
- chr10:6,709,530–6,740,532, 1 gene, copy number 10: LINP1.
- chr10:19,710,328–20,552,046, 11 genes, copy number 11: AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675.
- chr12:58,872,149–61,600,843, 22 genes, copy number 9: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52.
- chr14:35,826,338–39,432,500, 69 genes, copy number 9–37 (within-gene range 4–37) (broad region; genes not listed).
- chr17:29,197,071–30,360,566, 54 genes, copy number 9: AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P.
- chr17:52,390,515–53,106,358, 4 genes, copy number 9: LINC01982, LINC02089, LINC02876, MTCO1P40.
- chr17:53,353,427–53,439,721, 3 genes, copy number 9: AC005341.1, AC090079.1, AC090079.2.
- chr17:56,791,913–57,006,768, 14 genes, copy number 13 (within-gene range 8–13): C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3.
- chr17:58,951,185–59,401,729, 20 genes, copy number 13 (within-gene range 6–13): Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17, YPEL2, AC091059.2, MIR4729.
- chr17:66,302,613–66,810,743, 1 gene, copy number 9 (within-gene range 4–9): PRKCA.
- chr17:66,638,271–70,180,044, 90 genes, copy number 9 (broad region; genes not listed).
- chr17:71,097,774–71,871,750, 6 genes, copy number 9: CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1.
- chr18:1,357,651–2,049,510, 5 genes, copy number 9 (within-gene range 8–9): AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–1,929,094, 1 gene, copy number 9: AIDAP3.
- chr20:21,947,647–24,680,991, 69 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
